Somatic mutation profile of tumor specimen TARGET-20-PARPPY-40A (aliquot TARGET-20-PARPPY-40A-02D) from TARGET case TARGET-20-PARPPY, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.3 years (3,044 days).
Specimen TARGET-20-PARPPY-40A: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c28f72d0-880f-444d-9c11-a69eeef42de5.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARPPY-14A (Bone Marrow Normal), aliquot TARGET-20-PARPPY-14A-02D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc0286ba-b583-4aa0-a7ad-877d29e7b706

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1210C>T p.R404* | Nonsense Mutation (SNP) | VAF 26/147 reads (18%) | catalogued as rs373145711, CM116006, COSV60102210; ClinVar: pathogenic; called by muse, mutect2, varscan2
